EXCEPTIONAL_RESPONDERS case ER-ACFR — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/965a978e-92e7-463e-a976-8547a854db86

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Alive.

Diagnoses (1)
1. Signet ring cell adenocarcinoma: ICD-O-3 morphology code: 8490/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 53.1 years (19,382 days); Year of diagnosis: 2011; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,732 days (4.7 years); Days to best overall response: 468 days (1.3 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Cisplatin + Fluorouracil; Days to treatment start: 44 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Epirubicin Hydrochloride; Days to treatment start: 44 days; Days to treatment end: 329 days.
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 150 days.
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 150 days; Days to treatment end: 329 days.

Follow-up (1 entry)
- Days to follow up: 1,732 days (4.7 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 24 days; Days progression-free: 1,732 days (4.7 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ACFR-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ACFR-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 2; Percent tumor nuclei: 1; Percent normal cells: 98; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ACFR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ACFR-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 60; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
